Somatic mutation profile of tumor specimen TCGA-AA-3844-01A (aliquot TCGA-AA-3844-01A-01W-0995-10) from TCGA case TCGA-AA-3844, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 78.1 years (28,521 days).
Specimen TCGA-AA-3844-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d16a1b7-df78-4ff2-a02c-ebee34477142.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3844-10A (Blood Derived Normal), aliquot TCGA-AA-3844-10A-01W-0995-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd90e76c-01ea-4310-be3c-457272cd97a1

The open-access MAF lists 128 somatic variants for this specimen: 96 protein-altering or splice-affecting, 31 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 82, Silent 31, Nonsense Mutation 12, Splice Site 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 33/55 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 137/158 reads (87%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSM5 | c.1045G>T p.A349S | Missense Mutation (SNP) | VAF 179/640 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as COSV100088579; called by muse, mutect2, varscan2
- ADAMTS19 | c.3090G>T p.K1030N | Missense Mutation (SNP) | VAF 75/277 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV50762845; called by muse, mutect2, varscan2
- AGO4 | c.2311T>G p.W771G | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV100942822; called by muse, mutect2, varscan2
- ALPK2 | c.5963C>T p.A1988V | Missense Mutation (SNP) | VAF 97/147 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100864192; called by muse, mutect2, varscan2
- ANTXR1 | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 150/356 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.354); catalogued as rs149800589; called by muse, mutect2, varscan2
- ATP6V1C1 | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 183/458 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV67778129; called by muse, mutect2, varscan2
- BRAT1 | c.214G>A p.V72I | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.91); PolyPhen benign (0.012); catalogued as COSV61395614; called by muse, mutect2, varscan2
- CDH10 | c.1578C>A p.F526L | Missense Mutation (SNP) | VAF 112/541 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100050494, COSV100052698; called by mutect2, varscan2
- CDO1 | c.65T>C p.L22P | Missense Mutation (SNP) | VAF 76/295 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as COSV51665420; called by muse, mutect2, varscan2
- CEMIP2 | c.2821G>A p.E941K | Missense Mutation (SNP) | VAF 80/146 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV100987080; called by muse, mutect2, varscan2
- CER1 | c.562G>A p.G188R | Missense Mutation (SNP) | VAF 62/234 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101097812, COSV66603399; called by muse, mutect2, varscan2
- CHRDL1 | c.1227G>T p.Q409H (on ENST00000372045; = p.Q415H on NM_145234.4) | Missense Mutation (SNP) | VAF 384/703 reads (55%) | SIFT tolerated (0.6); PolyPhen benign (0.191); catalogued as COSV99487818; called by muse, mutect2, varscan2
- CIITA | c.888C>A p.D296E | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.519); catalogued as rs754504346, COSV60857814; called by muse, mutect2, varscan2
- CLCA4 | c.2122G>A p.G708R | Missense Mutation (SNP) | VAF 86/183 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs748985367, COSV55368285, COSV55369779; called by muse, mutect2, varscan2
- CNKSR2 | c.1115G>T p.C372F | Missense Mutation (SNP) | VAF 68/244 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.296); catalogued as COSV99667739; called by muse, mutect2, varscan2
- CNTN4 | c.1952T>C p.L651P | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.633); catalogued as COSV100638954; called by muse, mutect2
- COL5A3 | c.1150A>T p.I384F | Missense Mutation (SNP) | VAF 429/1057 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.486); catalogued as COSV99318379; called by muse, mutect2, varscan2
- CORIN | c.1668T>G p.D556E | Missense Mutation (SNP) | VAF 27/305 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV99903154; called by muse, mutect2
- CST11 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 52/682 reads (8%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.932); catalogued as rs1416856753, COSV65440810; called by muse, mutect2
- DCAF1 | c.4288G>A p.D1430N | Missense Mutation (SNP) | VAF 207/457 reads (45%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.981); catalogued as COSV100244189; called by muse, mutect2, varscan2
- DCX | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 20/360 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV100576253; called by muse, mutect2
- DDX53 | c.247C>G p.Q83E | Missense Mutation (SNP) | VAF 45/197 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.438); catalogued as COSV60069199; called by muse, mutect2, varscan2
- DICER1 | c.5677G>T p.V1893F | Missense Mutation (SNP) | VAF 319/783 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100601860; called by muse, mutect2, varscan2
- EFEMP1 | c.80C>T p.T27M | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.765); catalogued as rs768601184, COSV100816754; called by muse, mutect2, varscan2
- ESRRB | c.865G>A p.V289M | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs767944860, COSV55062367; called by muse, mutect2, varscan2
- EVC2 | c.797C>A p.T266N | Missense Mutation (SNP) | VAF 71/194 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV100185332; called by muse, mutect2, varscan2
- FILIP1 | c.1175G>T p.G392V | Missense Mutation (SNP) | VAF 17/596 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV99384112; called by muse, mutect2
- FOXA2 | c.545T>A p.L182Q (on ENST00000377115 / NM_153675.3; = p.L188Q on NM_021784.5) | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65796402; called by muse, mutect2, varscan2
- GBP7 | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.049); catalogued as COSV99642944; called by muse, mutect2, varscan2
- GRIA1 | c.1037T>C p.F346S | Missense Mutation (SNP) | VAF 240/985 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV99598665; called by muse, mutect2, varscan2
- GRIN2C | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as COSV99500687; called by muse, mutect2, varscan2
- GRM7 | c.2036G>A p.R679Q | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV63128926; called by muse, mutect2, varscan2
- GSN | c.2040+1G>T p.X680_splice | Splice Site (SNP) | VAF 130/249 reads (52%) | catalogued as COSV57998114; called by muse, mutect2, varscan2
- GSTCD | c.1555G>C p.A519P (on ENST00000360505 / NM_001031720.3; = p.A432P on NM_024751.3) | Missense Mutation (SNP) | VAF 832/2203 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100853788; called by muse, mutect2, varscan2
- HNRNPR | c.401C>A p.T134N | Missense Mutation (SNP) | VAF 12/296 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV100164356; called by muse, mutect2
- ICE1 | c.5236G>C p.E1746Q | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV56826420; called by muse, mutect2, varscan2
- IDE | c.802A>T p.T268S | Missense Mutation (SNP) | VAF 47/240 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.12); catalogued as COSV99793863; called by muse, mutect2, varscan2
- IGHG2 | c.550G>A p.V184I | Missense Mutation (SNP) | VAF 129/334 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.022); catalogued as rs774491393; called by muse, mutect2, varscan2
- INPP4A | c.1847C>A p.P616H (on ENST00000074304 / NM_001134224.1; = p.P577H on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 131/329 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV99302884; called by muse, mutect2, varscan2
- KCNT2 | c.3061C>A p.L1021M | Missense Mutation (SNP) | VAF 642/1551 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.285); catalogued as COSV99652217; called by muse, mutect2, varscan2
- KRT3 | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 45/75 reads (60%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.846); catalogued as rs770770484, COSV58814637; called by muse, mutect2, varscan2
- LRGUK | c.1780C>T p.Q594* | Nonsense Mutation (SNP) | VAF 44/797 reads (6%) | catalogued as COSV99603844; called by muse, mutect2
- MAB21L1 | c.41A>C p.K14T | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as COSV59788892; called by muse, mutect2, varscan2
- MID2 | c.868G>C p.V290L | Missense Mutation (SNP) | VAF 34/738 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV53309746; called by muse, mutect2
- MOGS | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as rs779319482, COSV99280864; called by muse, mutect2, varscan2
- MTMR12 | c.1480T>G p.F494V | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99373426; called by muse, mutect2, varscan2
- MUC16 | c.42022C>T p.P14008S | Missense Mutation (SNP) | VAF 97/256 reads (38%) | SIFT tolerated, low confidence (0.31); PolyPhen probably damaging (0.992); catalogued as rs1476603712, COSV101109693; called by muse, mutect2, varscan2
- NFASC | c.1136C>A p.S379* (on ENST00000339876 / NM_001378329.1; = p.S390* on NM_015090.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 63/167 reads (38%) | catalogued as COSV100362910, COSV58371425; called by muse, mutect2, varscan2
- NOS1 | c.394G>T p.A132S | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.003); catalogued as COSV100500206; called by muse, mutect2, varscan2
- OPCML | c.432C>A p.D144E | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV100098749, COSV59429603; called by muse, mutect2, varscan2
- OR4K5 | c.180C>A p.Y60* | Nonsense Mutation (SNP) | VAF 706/2806 reads (25%) | catalogued as COSV100262221; called by muse, mutect2, varscan2
- OXR1 | c.517G>C p.D173H (on ENST00000442977 / NM_001198532.1; = p.D172H on NM_018002.3) | Missense Mutation (SNP) | VAF 48/432 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV56336815; called by muse, mutect2, varscan2
- PCDH10 | c.116A>G p.E39G | Missense Mutation (SNP) | VAF 11/176 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV99993164; called by muse, mutect2
- PCDHGB2 | c.2375A>T p.N792I | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.03); catalogued as COSV53960369; called by muse, mutect2, varscan2
- PDE7B | c.253C>T p.L85F | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0.014); catalogued as COSV100367466; called by muse, mutect2, varscan2
- PDE8B | c.831C>G p.H277Q | Missense Mutation (SNP) | VAF 96/820 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV53738540; called by muse, mutect2, varscan2
- PDPR | c.601C>T p.Q201* | Nonsense Mutation (SNP) | VAF 22/120 reads (18%) | catalogued as COSV55349944, COSV55352747; called by muse, mutect2
- PKHD1L1 | c.7092C>A p.Y2364* | Nonsense Mutation (SNP) | VAF 46/132 reads (35%) | catalogued as COSV65748966; called by muse, mutect2, varscan2
- POLR3A | c.2686G>A p.D896N | Missense Mutation (SNP) | VAF 133/327 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.805); catalogued as rs773941193, COSV64931157; called by muse, mutect2, varscan2
- PPM1L | c.980G>T p.G327V | Missense Mutation (SNP) | VAF 68/215 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55564958; called by muse, mutect2, varscan2
- PPP2R2C | c.1169C>T p.P390L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.665); catalogued as COSV100160296; called by muse, varscan2
- PROM2 | c.595G>A p.G199S | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.401); catalogued as COSV100468753; called by muse, mutect2, varscan2
- PUM3 | c.373C>T p.Q125* | Nonsense Mutation (SNP) | VAF 34/626 reads (5%) | catalogued as COSV101193153; called by muse, mutect2
- RABGAP1 | c.3018G>T p.Q1006H | Missense Mutation (SNP) | VAF 118/205 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV101016689; called by muse, mutect2, varscan2
- REXO5 | c.1626+1G>T p.X542_splice | Splice Site (SNP) | VAF 61/127 reads (48%) | catalogued as COSV99759031; called by muse, mutect2, varscan2
- RNF25 | c.844A>G p.K282E | Missense Mutation (SNP) | VAF 80/215 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55307824; called by muse, mutect2, varscan2
- SCN10A | c.3100C>T p.Q1034* | Nonsense Mutation (SNP) | VAF 39/176 reads (22%) | catalogued as COSV101479282, COSV71862900; called by muse, mutect2, varscan2
- SCN9A | c.2488G>T p.G830* (on ENST00000303354; = p.G819* on NM_002977.3) | Nonsense Mutation (SNP) | VAF 94/253 reads (37%) | catalogued as rs1553488198, COSV100311859; called by muse, mutect2, varscan2
- SETBP1 | c.1694C>A p.T565N | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99952400; called by muse, mutect2, varscan2
- SLC19A2 | c.555G>A p.W185* | Nonsense Mutation (SNP) | VAF 35/88 reads (40%) | catalogued as COSV52547533; called by muse, mutect2, varscan2
- SLC44A1 | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 1088/4045 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as COSV58264742, COSV58266211; called by muse, mutect2, varscan2
- SLC7A8 | c.1543C>T p.Q515* | Nonsense Mutation (SNP) | VAF 68/1046 reads (7%) | catalogued as COSV100328281; called by muse, mutect2
- SLCO1B3 | c.980A>T p.Q327L | Missense Mutation (SNP) | VAF 102/319 reads (32%) | SIFT tolerated (0.69); PolyPhen benign (0.038); catalogued as COSV99681038; called by muse, mutect2, varscan2
- SLCO3A1 | c.1255G>C p.G419R | Missense Mutation (SNP) | VAF 413/1149 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as COSV100575054; called by muse, mutect2, varscan2
- SMARCAD1 | c.1547T>A p.L516H | Missense Mutation (SNP) | VAF 48/1652 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100758798; called by muse, mutect2
- SPP1 | c.822C>A p.H274Q (on ENST00000395080 / NM_001040058.2; = p.H260Q on NM_000582.2) | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.68); PolyPhen benign (0.015); catalogued as COSV52951910; called by muse, mutect2, varscan2
- SPPL2C | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 23/29 reads (79%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1248867414, COSV61292647; called by muse, mutect2, varscan2
- STX18 | c.542C>T p.T181I | Missense Mutation (SNP) | VAF 31/704 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100086067; called by muse, mutect2
- SUSD4 | c.763G>A p.V255I | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377586871; called by muse, mutect2, varscan2
- SYCE2 | c.58C>A p.P20T | Missense Mutation (SNP) | VAF 80/205 reads (39%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.107); catalogued as COSV53366806; called by muse, mutect2, varscan2
- TECTA | c.2428C>T p.R810* | Nonsense Mutation (SNP) | VAF 101/238 reads (42%) | catalogued as rs758974282, CM143787, COSV50687629, COSV50698738; called by muse, mutect2, varscan2
- TMEM132D | c.2345G>A p.R782Q | Missense Mutation (SNP) | VAF 330/1081 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746232750, COSV67158852; called by muse, mutect2, varscan2
- TMEM163 | c.244C>A p.Q82K | Missense Mutation (SNP) | VAF 55/177 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV99925826; called by muse, mutect2, varscan2
- TOMM34 | c.262C>A p.L88M | Missense Mutation (SNP) | VAF 48/75 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100861887, COSV65689264; called by muse, mutect2, varscan2
- TRIOBP | c.1241C>A p.A414D | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.665); catalogued as COSV60378473; called by muse, mutect2, varscan2
- TTN | c.56785C>A p.P18929T (on ENST00000591111; = p.P11505T on NM_003319.4) | Missense Mutation (SNP) | VAF 69/175 reads (39%) | PolyPhen probably damaging (0.999); catalogued as COSV100600080; called by muse, mutect2, varscan2
- UGGT2 | c.2942T>C p.M981T | Missense Mutation (SNP) | VAF 136/254 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV100948521; called by muse, mutect2, varscan2
- VCAM1 | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.339); catalogued as rs754424141, COSV104399163, COSV54117622; called by muse, mutect2, varscan2
- VPS41 | c.2186G>A p.R729H | Missense Mutation (SNP) | VAF 148/530 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780108229, COSV59653519; called by muse, mutect2, varscan2
- YTHDC2 | c.1968C>G p.Y656* | Nonsense Mutation (SNP) | VAF 8/65 reads (12%) | catalogued as COSV99363027; called by muse, mutect2
- ZNF215 | c.1300G>A p.A434T | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV53492819, COSV53493367; called by muse, mutect2, varscan2
- ZNF235 | c.2081A>T p.Q694L | Missense Mutation (SNP) | VAF 144/376 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV99349298; called by muse, mutect2, varscan2
- PAM | c.784A>G p.S262G | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); called by muse, varscan2
- TPTE | c.1474T>A p.C492S (on ENST00000618007 / NM_199261.4; = p.C474S on NM_199259.4) | Missense Mutation (SNP) | VAF 123/627 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- ABCA1 | c.1785C>T p.Y595= | Silent (SNP) | VAF 137/474 reads (29%) | catalogued as COSV66066972; called by muse, mutect2, varscan2
- ALPP | c.1245C>T p.Y415= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as rs752955692, COSV67396201, COSV67396216; called by muse, mutect2, varscan2
- APOB | c.10944C>T p.V3648= | Silent (SNP) | VAF 110/282 reads (39%) | catalogued as rs370314131; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARHGAP9 | c.1563G>A p.A521= (on ENST00000393797 / NM_001319850.2; = p.A502= on NM_032496.4) | Silent (SNP) | VAF 47/178 reads (26%) | catalogued as rs888963637, COSV57362926; called by muse, mutect2, varscan2
- ARL11 | c.216C>A p.A72= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as COSV56291377; called by muse, mutect2, varscan2
- ASAP1 | c.2934A>G p.S978= | Silent (SNP) | VAF 197/440 reads (45%) | catalogued as COSV100726950; called by muse, mutect2, varscan2
- BDP1 | c.6579A>G p.E2193= | Silent (SNP) | VAF 38/144 reads (26%) | catalogued as COSV62431751; called by mutect2, varscan2
- BICC1 | c.2100C>T p.R700= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs537675644, COSV54065048; called by muse, mutect2, varscan2
- BRWD3 | c.3594C>G p.R1198= | Silent (SNP) | VAF 15/98 reads (15%) | catalogued as COSV100955783; called by muse, mutect2, varscan2
- CHD5 | c.4281A>G p.R1427= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV99312846; called by muse, mutect2
- CLCA2 | c.1140G>A p.L380= | Silent (SNP) | VAF 53/303 reads (17%) | catalogued as COSV65287392; called by muse, mutect2, varscan2
- DGKI | c.2193C>T p.I731= | Silent (SNP) | VAF 513/932 reads (55%) | catalogued as rs1359868807, COSV99932930; called by muse, mutect2, varscan2
- FAM90A1 | c.57C>A p.T19= | Silent (SNP) | VAF 16/118 reads (14%) | catalogued as COSV56712444; called by muse, mutect2, varscan2
- FAT3 | c.9525T>A p.G3175= | Silent (SNP) | VAF 14/103 reads (14%) | catalogued as COSV53119042; called by muse, mutect2
- FN1 | c.6843C>T p.N2281= (on ENST00000359671 / NM_001365524.2; = p.N2250= on NM_002026.4) | Silent (SNP) | VAF 163/387 reads (42%) | catalogued as rs568449322, COSV60546476; called by muse, mutect2, varscan2
- GALNT13 | c.1569C>T p.L523= | Silent (SNP) | VAF 128/376 reads (34%) | catalogued as rs371789307, COSV67222912; called by muse, mutect2, varscan2
- GYG2 | c.471G>A p.P157= | Silent (SNP) | VAF 149/470 reads (32%) | catalogued as rs372618531, COSV58550147; called by muse, mutect2, varscan2
- IFIT5 | c.940C>T p.L314= | Silent (SNP) | VAF 38/85 reads (45%) | catalogued as COSV65655339, COSV65655630; called by muse, mutect2, varscan2
- ITGA11 | c.1734C>T p.H578= | Silent (SNP) | VAF 240/281 reads (85%) | catalogued as rs771219909, COSV100241124; called by muse, mutect2, varscan2
- MITF | c.1128C>T p.H376= (on ENST00000448226 / NM_006722.3; = p.H276= on NM_000248.4) | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as rs748181332, COSV58832098; called by muse, mutect2, varscan2
- MRPL4 | c.639G>C p.G213= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV53448189, COSV53450142; called by muse, mutect2, varscan2
- NKX2-5 | c.876C>T p.F292= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as rs538010963, COSV61298720; called by muse, mutect2, varscan2
- PCDHA5 | c.1350C>T p.N450= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs61730629, COSV65348992; called by muse, mutect2, varscan2
- PML | c.630G>T p.P210= | Silent (SNP) | VAF 28/46 reads (61%) | catalogued as rs767815962, COSV51447319; called by muse, mutect2, varscan2
- SCGB2A2 | c.153C>T p.D51= | Silent (SNP) | VAF 281/600 reads (47%) | catalogued as rs749846065, COSV57174635; called by muse, mutect2, varscan2
- SCGN | c.672G>T p.G224= | Silent (SNP) | VAF 455/1201 reads (38%) | catalogued as rs1174126631, COSV58545766; called by muse, mutect2, varscan2
- SF3A1 | c.1695C>T p.N565= | Silent (SNP) | VAF 388/1040 reads (37%) | catalogued as rs988552549, COSV53169267; called by muse, mutect2, varscan2
- SSTR2 | c.327C>G p.P109= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV59535278; called by muse, mutect2, varscan2
- TIMP4 | c.606C>T p.D202= | Silent (SNP) | VAF 47/103 reads (46%) | catalogued as rs765096492, COSV55138642; called by muse, mutect2, varscan2
- TRPV4 | c.1797G>A p.T599= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as rs747018354, COSV55682635, COSV99924548; called by muse, mutect2, varscan2
- ZNF536 | c.513G>T p.G171= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV100835115, COSV62825377; called by muse, mutect2, varscan2
- KRT222 | c.-2G>A | 5'UTR (SNP) | VAF 67/1106 reads (6%) | catalogued as COSV101229473; called by muse, mutect2
